Surgical pathology report (de-identified scan), TCGA case TCGA-55-8301, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8301-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

COPY TO:

Pre-Op Diagnosis
Lung mass
Post-Op Diagnosis
Same as above
Clinical History
Nothing indicated
Gross Description:
Four parts

Container labeled [REDACTED] - right lung lower lobe" has a previously partially inked, previously partially sectioned recognizable portion of pulmonary parenchyma consistent with right lower lobe. The specimen as received weighs 209 grams and is received after tissue harvest for genomic study. Within the specimen container are two tissue cassettes labeled [REDACTED]. The right lower lobe as received measures 15.0 x 13.6 x 5.0 cm and has as its margin of resection stapled bronchial margin. The pleura is smooth and moderately anthracotic streaked. On the posterior upper aspect extending laterally, the specimen is previously partially sectioned to reveal a 3.0 x 2.8 x 2.7 cm irregular tan-gray fibrotic lesion which is noted subpleurally. This extends to but not through the pleura in this area. This has a markedly anthracotic streaked friable gray-tan fibrotic cut surface. This is noted at its nearest point 3.5 cm from the nearest bronchial margin. An apparent bronchial connection is identified. Immediately surrounding the lesion is a moderate amount of cavitory emphysema. The remaining parenchyma is spongy and congested with marked anthracotic streaking and areas of apparent gross emphysema. Representative sections are submitted labeled as follows: A - shaved bronchial margin; B-F - lesion and surrounding tissue; G - random uninvolved parenchyma.

Container labeled [REDACTED] level 9 lymph node right lung"

[REDACTED]

[page 2 of 3]
has 1.2 x 1.0 x 0.3 cm of gray-red to black shaggy tissue fragments, entirely submitted in a single cassette.

Container labeled [REDACTED] level 4 lymph node right lung" has two irregular roughly nodular portions of gray-black fleshy tissue with surrounding fibroadipose tissue. The portions together measure 2.0 x 1.0 x 0.5 cm. Specimen is sectioned and entirely submitted in a single cassette.

Container labeled [REDACTED] level 10 lymph node right lung" has two irregular fragments of gray-black fleshy tissue, 0.7 x 0.4 x 0.3 cm and 1.0 x 0.5 x 0.3 cm. Specimen is entirely submitted in a single cassette.

[REDACTED]
Microscopic Description:
Reviewed are slides labeled [REDACTED]

Final Diagnosis

Lung, right lower lobe, lobectomy:

Tumor characteristics:

Specimen integrity: Intact.

Specimen laterality: Unilateral.

Histologic type: Adenocarcinoma.

Grade: Moderate to poorly differentiated (grade 2-3).

Tumor site: Right lower lobe, posterior and lateral.

Tumor focality: Unifocal.

Tumor size: 3.0 x 2.8 x 2.7 cm.

Visceral pleural invasion: Tumor extends through the elastic layer (see comment).

Lymphovascular space invasion: Multiple foci suspicious for vascular invasion identified.

Tumor extension: Tumor confined to lung.

Treatment effect: Not identified/not known.

Surgical margin status:

Tumor distance from bronchial margin: 3.5 cm

Tumor distance from pleural surface: Tumor extends less than 1 mm from pleural surface but does not extend through pleura.

Lymph node status:

Total number of lymph nodes received with lobectomy specimen (peribronchial): 1

Total number of lymph nodes containing metastatic carcinoma: 0 (0/1)

See also parts 2, 3, and 4.

Other: Minimal emphysematous change.

Stage: pT2aN0

Lymph node, level 9, excision:

Multiple fragments of benign lymph node (0/1).

Lymph node, level 4, right lung, excision:

Two lymph nodes negative for metastatic carcinoma (0/2).

Lymph node, level 10, right lung, excision:

Two lymph nodes negative for metastatic carcinoma (0/2). [REDACTED]

[REDACTED]
[REDACTED]
Comments

Histologic sections from the lung mass demonstrate a moderate to poorly differentiated adenocarcinoma morphologically compatible with pulmonary origin. The tumor abuts the inked pleural surface along a [REDACTED]

[page 3 of 3]
broad front. Multiple sections from this area demonstrate the tumor to extend through the elastic layer to within 1 mm of the pleural surface. These findings are confirmed by elastic stain with working control. Extension through the pleural surface, however, is not identified in sections examined. Clinical correlation and correlation with intraoperative findings is recommended.

At the request of the undersigned pathologist, these slides have been additionally reviewed by Dr. [REDACTED] who concurs with the diagnosis.

This report has been finalized at the [REDACTED]

<Sign Out Dr. Signature>

[REDACTED]

Source: NCI Genomic Data Commons file c0decbec-d33b-4893-aa1b-8744362f1cf9 (TCGA-55-8301.55B2132A-EC1C-47A7-B91B-65F48C45FCB5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).